Somatic mutation profile of tumor specimen TCGA-59-2363-01A (aliquot TCGA-59-2363-01A-01W-0799-08) from TCGA case TCGA-59-2363, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: G3.
Specimen TCGA-59-2363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dec4bb2f-d71f-487b-af9d-fb7ff707e634.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-59-2363-10A (Blood Derived Normal), aliquot TCGA-59-2363-10A-01W-0800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37d9692b-67ad-436b-81f6-7ecb13bbd00e

The open-access MAF lists 84 somatic variants for this specimen: 65 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 16, Nonsense Mutation 4, Intron 2, Splice Site 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779629, CM000319, CM1412433, COSV58584704; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 72/85 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ADAMTSL3 | c.2104C>A p.P702T | Missense Mutation (SNP) | VAF 256/395 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV54440327, COSV54441134; called by muse, mutect2, varscan2
- ADGRE3 | c.1003T>A p.C335S | Missense Mutation (SNP) | VAF 103/344 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.58); catalogued as COSV53729244; called by muse, mutect2, varscan2
- AKAP6 | c.4558C>A p.P1520T | Missense Mutation (SNP) | VAF 98/408 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV55208733; called by muse, mutect2, varscan2
- ANK2 | c.11717G>A p.R3906Q | Missense Mutation (SNP) | VAF 116/136 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs770001324, COSV52151566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD11 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV56357807; called by muse, mutect2, varscan2
- CCDC60 | c.1600T>A p.W534R | Missense Mutation (SNP) | VAF 260/449 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100555149; called by muse, mutect2, varscan2
- CDH22 | c.1588G>T p.G530C | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV64836939; called by muse, mutect2, varscan2
- CFAP58 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 85/184 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV57211656; called by muse, mutect2, varscan2
- CFAP91 | c.2048G>A p.S683N | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV56340002; called by muse, mutect2, varscan2
- CLTCL1 | c.3416A>T p.E1139V | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV54227249; called by muse, mutect2, varscan2
- CSMD3 | c.7418G>A p.G2473E (on ENST00000297405 / NM_001363185.1; = p.G2369E on NM_052900.3) | Missense Mutation (SNP) | VAF 117/425 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs533489245, COSV52135036; called by muse, mutect2, varscan2
- DNAH10 | c.5645C>T p.A1882V (on ENST00000409039; = p.A1821V on NM_207437.3) | Missense Mutation (SNP) | VAF 142/561 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755398032, COSV68990430; called by muse, mutect2, varscan2
- ENTPD3 | c.694G>T p.G232* | Nonsense Mutation (SNP) | VAF 34/161 reads (21%) | catalogued as COSV57193816; called by muse, mutect2, varscan2
- F5 | c.1567C>A p.L523I | Missense Mutation (SNP) | VAF 136/262 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); catalogued as COSV63122231, COSV63124980; called by muse, mutect2, varscan2
- FRAS1 | c.9058G>T p.G3020* | Nonsense Mutation (SNP) | VAF 201/247 reads (81%) | catalogued as COSV99352400; called by muse, mutect2, varscan2
- FRAS1 | c.9059G>T p.G3020V | Missense Mutation (SNP) | VAF 203/250 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53629255, COSV99352405; called by muse, mutect2, varscan2
- GOLGB1 | c.9285G>T p.K3095N | Missense Mutation (SNP) | VAF 16/393 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV61461918, COSV61468660; called by muse, mutect2
- GPHB5 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 126/292 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100030133, COSV58485736; called by muse, mutect2, varscan2
- GPR4 | c.946A>G p.M316V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV59916460; called by muse, mutect2, varscan2
- H3C11 | c.298T>C p.Y100H | Missense Mutation (SNP) | VAF 103/244 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.392); catalogued as COSV58899501; called by muse, mutect2, varscan2
- IL1RL2 | c.1618A>T p.R540W | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51814096; called by muse, mutect2, varscan2
- ISOC2 | c.484G>A p.E162K (on ENST00000425675 / NM_001136201.2; = p.E178K on NM_024710.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs757745171, COSV50034874; called by muse, mutect2, varscan2
- KIF5A | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 80/91 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54052817, COSV54058548; called by muse, mutect2, varscan2
- KNTC1 | c.1344G>C p.Q448H | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV61079406; called by muse, mutect2, varscan2
- LYST | c.5015T>G p.L1672R | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101089483; called by muse, mutect2, varscan2
- MAGEB2 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs369826731, COSV66780470; called by muse, mutect2, varscan2
- MICAL1 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV57804666; called by muse, mutect2, varscan2
- MYO5C | c.2145G>T p.E715D | Missense Mutation (SNP) | VAF 281/679 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs779334434, COSV55904243; called by muse, mutect2, varscan2
- NBEA | c.749A>C p.K250T | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV59769661, COSV59834850; called by muse, mutect2, varscan2
- NF1 | c.6640G>T p.E2214* (on ENST00000358273 / NM_001042492.3; = p.E2193* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 70/81 reads (86%) | catalogued as CD001525, COSV62197449; called by muse, mutect2, varscan2
- NLRX1 | c.2429C>T p.T810M | Missense Mutation (SNP) | VAF 113/253 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs148037206; called by muse, mutect2, varscan2
- NPAS2 | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0.03); catalogued as COSV59556413; called by muse, mutect2, varscan2
- ODAM | c.73T>A p.S25T | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV68572480; called by muse, mutect2, varscan2
- OR10T2 | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147666373, COSV57780708; called by muse, mutect2, varscan2
- OR14J1 | c.519C>A p.H173Q | Missense Mutation (SNP) | VAF 439/1132 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV65845579; called by muse, mutect2, varscan2
- OR52E2 | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 57/161 reads (35%) | catalogued as COSV58612171; called by muse, mutect2, varscan2
- OR9Q2 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs375904836; called by muse, mutect2, varscan2
- PARP4 | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); catalogued as COSV67960769; called by muse, mutect2, varscan2
- PCED1A | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV62313495, COSV62313831; called by muse, mutect2, varscan2
- PLCL2 | c.445C>A p.L149I (on ENST00000615277 / NM_001144382.2; = p.L23I on NM_015184.5) | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV67621305; called by muse, mutect2, varscan2
- PLEC | c.8761C>G p.Q2921E (on ENST00000322810 / NM_201380.4; = p.Q2811E on NM_000445.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59616858; called by muse, mutect2, varscan2
- PLOD2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs148641011; called by muse, mutect2, varscan2
- POLR1G | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV56233704; called by muse, mutect2, varscan2
- PRKACG | c.757T>C p.S253P | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV55243855; called by muse, mutect2, varscan2
- PYGM | c.2446C>G p.R816G | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51215458; called by muse, mutect2, varscan2
- RAD50 | c.3743C>G p.A1248G | Missense Mutation (SNP) | VAF 759/816 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV54749291; called by muse, mutect2, varscan2
- RNF123 | c.2969T>A p.L990Q | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV57537964; called by muse, mutect2, varscan2
- SCAPER | c.3725G>C p.G1242A | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57736588; called by muse, mutect2, varscan2
- SCLT1 | c.1280A>T p.E427V | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55403442; called by muse, mutect2, varscan2
- SLC35F6 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as COSV60426189; called by muse, mutect2, varscan2
- SNX25 | c.1635G>C p.K545N | Missense Mutation (SNP) | VAF 237/277 reads (86%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV53012689; called by muse, mutect2, varscan2
- SORCS1 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99546924; called by muse, mutect2, varscan2
- SORCS1 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV53901488; called by muse, mutect2, varscan2
- SPATS2L | c.1532G>C p.R511T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as COSV62346591; called by muse, mutect2, varscan2
- SPTB | c.1276C>A p.R426S | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67630604; called by muse, mutect2
- SYNE1 | c.20701A>G p.K6901E (on ENST00000367255 / NM_182961.4; = p.K6830E on NM_033071.3) | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV54938183; called by muse, mutect2, varscan2
- SYNE1 | c.14124G>T p.E4708D (on ENST00000367255 / NM_182961.4; = p.E4637D on NM_033071.3) | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV54938198; called by muse, mutect2, varscan2
- TMEFF2 | c.155C>A p.T52N | Missense Mutation (SNP) | VAF 85/321 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.61); catalogued as COSV99771653; called by muse, mutect2, varscan2
- TRPS1 | c.2665C>T p.R889C (on ENST00000220888 / NM_001330599.2; = p.R902C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/349 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55231899; called by muse, mutect2, varscan2
- UBC | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 135/498 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.402); catalogued as rs782796405, COSV60058853, COSV60060535; called by muse, mutect2, varscan2
- YBX3 | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54384940; called by muse, mutect2, varscan2
- COLGALT2 | c.1398-3_1421del p.X466_splice | Splice Site (DEL) | VAF 72/463 reads (16%) | called by mutect2, pindel
- TTC6 | c.380_391del p.D127_T130del (on ENST00000267368; = p.D1493_T1496del on NM_001310135.3) | In Frame Del (DEL) | VAF 137/381 reads (36%) | called by mutect2, pindel, varscan2
- CMTR1 | c.474T>C p.F158= | Silent (SNP) | VAF 92/182 reads (51%) | catalogued as COSV65089872; called by muse, mutect2, varscan2
- EPHB1 | c.2283C>T p.S761= | Silent (SNP) | VAF 457/1102 reads (41%) | catalogued as rs555858727, COSV101213411, COSV67654919; called by muse, mutect2, varscan2
- LRFN1 | c.1305G>A p.S435= | Silent (SNP) | VAF 26/43 reads (60%) | catalogued as COSV50436475; called by muse, mutect2, varscan2
- LRRC66 | c.2418C>G p.P806= | Silent (SNP) | VAF 73/86 reads (85%) | catalogued as COSV58632761; called by muse, mutect2, varscan2
- LYPD4 | c.675A>C p.A225= | Silent (SNP) | VAF 126/304 reads (41%) | catalogued as COSV58027581; called by muse, mutect2, varscan2
- MAP2 | c.4629A>G p.R1543= | Silent (SNP) | VAF 57/151 reads (38%) | catalogued as rs769478406, COSV52285405; called by muse, mutect2, varscan2
- NOMO1 | c.3258A>C p.P1086= | Silent (SNP) | VAF 297/378 reads (79%) | catalogued as COSV55057689; called by muse, mutect2, varscan2
- OR8K5 | c.786C>A p.P262= | Silent (SNP) | VAF 24/213 reads (11%) | catalogued as COSV57888225; called by muse, mutect2, varscan2
- PLCL1 | c.1791C>T p.Y597= | Silent (SNP) | VAF 93/339 reads (27%) | catalogued as COSV70823695; called by muse, mutect2, varscan2
- QKI | c.810A>T p.P270= | Silent (SNP) | VAF 143/382 reads (37%) | catalogued as COSV51691124; called by muse, mutect2, varscan2
- TACR3 | c.1338T>A p.S446= | Silent (SNP) | VAF 303/350 reads (87%) | catalogued as COSV59199579, COSV59206181; called by muse, mutect2, varscan2
- TBX5 | c.1350G>A p.L450= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as rs1213402848, COSV59859408; called by muse, mutect2, varscan2
- THEG | c.1125C>T p.P375= | Silent (SNP) | VAF 45/51 reads (88%) | catalogued as COSV61073470, COSV61074682; called by muse, mutect2, varscan2
- TNS1 | c.1449C>G p.A483= | Silent (SNP) | VAF 132/309 reads (43%) | catalogued as COSV99410831; called by muse, mutect2, varscan2
- TYMP | c.525G>A p.V175= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as COSV52687046; called by muse, mutect2, varscan2
- VPS35L | c.2487C>T p.S829= | Silent (SNP) | VAF 79/88 reads (90%) | catalogued as rs552801502, COSV51989375; called by muse, mutect2, varscan2
- ANKRD13D | c.*1194G>A | 3'UTR (SNP) | VAF 24/35 reads (69%) | catalogued as COSV100354447, COSV57383905; called by muse, mutect2, varscan2
- CAST | c.951+890C>G | Intron (SNP) | VAF 542/595 reads (91%) | catalogued as COSV57783480, COSV57784995; called by muse, mutect2, varscan2
- MACF1 | c.15832-8654C>T | Intron (SNP) | VAF 24/26 reads (92%) | catalogued as COSV57113067; called by muse, varscan2
